EXCEPTIONAL_RESPONDERS case ER-AD0W — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f1cb5403-db22-40af-a301-add38419915d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1965; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 48.4 years (17,669 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 796 days (2.2 years); Days to best overall response: 73 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 17 days; Days to treatment end: 711 days (1.9 years).

Follow-up (1 entry)
- Days to follow up: 796 days (2.2 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 796 days (2.2 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AD0W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-AD0W-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 40; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
